Somatic mutation profile of tumor specimen MMRF_2122_1_BM_CD138pos (aliquot MMRF_2122_1_BM_CD138pos_T1_KHS5U_L08140) from MMRF case MMRF_2122, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.0 years (24,480 days).
Specimen MMRF_2122_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2cab1e8-c324-4bb2-a820-71198fcc0ac2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2122_2_PB_Whole (Blood Derived Normal), aliquot MMRF_2122_2_PB_Whole_C1_KHS5U_L08141; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c94c4ff2-5643-4d3f-a3e9-83eed57f261e

The open-access MAF lists 75 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 21, Silent 12, 5'Flank 3, Intron 3, Nonsense Mutation 2, Splice Region 2, 5'UTR 2, Frame Shift Del 1, 3'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BICRA | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 138/296 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1488443734; called by muse, mutect2, varscan2
- BIRC6 | c.9130A>G p.S3044G | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs144025041, COSV101429488; called by muse, mutect2, varscan2
- CCT8L2 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1461798692; called by muse, mutect2, varscan2
- CENPM | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs774792724; called by muse, mutect2, varscan2
- ERCC3 | c.1155C>G p.D385E | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.161); catalogued as rs371396764; called by muse, mutect2, varscan2
- GPRASP2 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59990351; called by muse, mutect2, varscan2
- H1-5 | c.125del p.P42Qfs*5 | Frame Shift Del (DEL) | VAF 66/193 reads (34%) | catalogued as rs1387749224; called by pindel, varscan2
- HERC2 | c.10585C>T p.P3529S | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs754366545; called by muse, mutect2, varscan2
- IGHD6-6 | c.12C>G p.S4R | Missense Mutation (SNP) | VAF 72/73 reads (99%) | PolyPhen probably damaging (0.986); catalogued as rs529699011; called by muse, varscan2
- LRIG3 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1046332185; called by muse, mutect2, varscan2
- MAS1L | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); catalogued as rs768922382, COSV65809104; called by muse, mutect2, varscan2
- TELO2 | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 158/308 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1204132834; called by muse, mutect2, varscan2
- VPS13D | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 81/171 reads (47%) | catalogued as rs1216395626; called by muse, mutect2, varscan2
- CACYBP | c.271A>T p.I91F | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CRYBG2 | c.3556A>G p.S1186G | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- CTSF | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.8276G>T p.G2759V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GFUS | c.261+8A>T | Splice Region (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- LRRTM4 | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- MTHFD1 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH1 | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR2A14 | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PIGL | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 124/243 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKDC | c.11320A>T p.I3774F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- RESF1 | c.2633A>G p.E878G | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, varscan2
- RESF1 | c.2707A>G p.T903A | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, varscan2
- SAR1B | c.179-6A>G | Splice Region (SNP) | VAF 194/405 reads (48%) | called by muse, varscan2
- SEMA6C | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2
- TEAD2 | c.1069_1077+11del p.X357_splice | Splice Site (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- TMPRSS5 | c.442T>A p.C148S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAN | c.10042C>T p.P3348S | Missense Mutation (SNP) | VAF 127/241 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.6087T>C p.P2029= | Silent (SNP) | VAF 127/249 reads (51%) | called by muse, mutect2, varscan2
- AL157392.5 | c.583C>T p.L195= | Silent (SNP) | VAF 51/132 reads (39%) | called by muse, mutect2
- CALCR | c.819A>G p.Q273= (on ENST00000649521 / NM_001164737.2; = p.Q257= on NM_001742.4) | Silent (SNP) | VAF 154/335 reads (46%) | called by muse, mutect2, varscan2
- EXD1 | c.301C>T p.L101= | Silent (SNP) | VAF 116/257 reads (45%) | called by muse, mutect2, varscan2
- GIGYF2 | c.3885G>T p.T1295= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs774560951, COSV65246805; called by muse, mutect2, varscan2
- IGHD6-6 | c.18C>G p.S6= | Silent (SNP) | VAF 61/63 reads (97%) | called by muse, varscan2
- IGLV3-16 | c.162C>T p.Y54= | Silent (SNP) | VAF 64/69 reads (93%) | catalogued as rs529492618; called by muse, mutect2, varscan2
- LRP3 | c.1335C>T p.D445= | Silent (SNP) | VAF 88/174 reads (51%) | catalogued as rs762664449; called by muse, varscan2
- MUC6 | c.5373C>T p.S1791= | Silent (SNP) | VAF 60/566 reads (11%) | catalogued as rs1382426228; called by muse, varscan2
- NYNRIN | c.5029C>T p.L1677= | Silent (SNP) | VAF 58/111 reads (52%) | catalogued as rs1462836405; called by muse, mutect2, varscan2
- STK17A | c.36C>T p.S12= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as rs1563141110, COSV60046749; called by muse, mutect2, varscan2
- WDR24 | c.1326C>T p.S442= (on ENST00000248142; = p.S312= on NM_032259.4) | Silent (SNP) | VAF 77/167 reads (46%) | called by muse, mutect2, varscan2
- AC010928.1 | n.79C>T | RNA (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- AP001267.5 | c.-799+33342T>C | Intron (SNP) | VAF 65/125 reads (52%) | called by muse, mutect2, varscan2
- ARMH4 | c.*1361T>G | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2
- ATF2 | c.*1136C>T | 3'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as rs1441623906; called by muse, varscan2
- BAALC | chr8:103229966 T>A | 3'Flank (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021492 C>G | 5'Flank (SNP) | VAF 50/100 reads (50%) | catalogued as COSV55846308, COSV55846472; called by muse, mutect2, varscan2
- CHRNA4 | c.*144G>T | 3'UTR (SNP) | VAF 60/121 reads (50%) | called by muse, mutect2, varscan2
- DHFR2 | c.*1606A>G | 3'UTR (SNP) | VAF 4/96 reads (4%) | catalogued as rs890427110; called by muse, mutect2
- ETV1 | c.*478C>A | 3'UTR (SNP) | VAF 22/48 reads (46%) | catalogued as rs756393569; called by muse, mutect2
- IGHJ6 | chr14:105863437 A>T | 5'Flank (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- KMO | c.*643_*644insCCTA | 3'UTR (INS) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- LIMCH1 | c.*289T>C | 3'UTR (SNP) | VAF 26/59 reads (44%) | catalogued as rs1462748547; called by muse, mutect2
- NINJ2 | c.-32C>T | 5'UTR (SNP) | VAF 110/219 reads (50%) | catalogued as rs747050059, COSV59324291; called by muse, mutect2, varscan2
- P2RY2 | c.*836G>T | 3'UTR (SNP) | VAF 46/97 reads (47%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-2301C>T | Intron (SNP) | VAF 103/198 reads (52%) | called by muse, mutect2, varscan2
- POR | c.*225G>A | 3'UTR (SNP) | VAF 51/91 reads (56%) | catalogued as rs375406404; called by muse, mutect2, varscan2
- PPP1CA | c.-74G>A | 5'UTR (SNP) | VAF 27/57 reads (47%) | catalogued as rs1475611492; called by muse, mutect2, varscan2
- RNF145 | c.*1075T>C | 3'UTR (SNP) | VAF 102/182 reads (56%) | called by muse, mutect2
- RNF145 | c.*1073T>C | 3'UTR (SNP) | VAF 104/188 reads (55%) | called by muse, mutect2
- SPA17 | c.*54T>C | 3'UTR (SNP) | VAF 91/187 reads (49%) | called by muse, mutect2, varscan2
- SPA17 | c.*168del | 3'UTR (DEL) | VAF 28/92 reads (30%) | called by pindel, varscan2
- SPA17 | c.*247A>G | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, varscan2
- SPA17 | c.*599T>A | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2
- SPA17 | c.*2519T>G | 3'UTR (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- SPA17 | c.*2670C>T | 3'UTR (SNP) | VAF 55/116 reads (47%) | called by muse, mutect2, varscan2
- SST | c.*108T>C | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- TBX5 | c.*528C>A | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- TCF4 | c.287-9002C>T | Intron (SNP) | VAF 26/49 reads (53%) | catalogued as rs146003827; called by muse, mutect2, varscan2
- TMBIM6 | c.*1530C>T | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, varscan2
- TXNRD3 | chr3:126655123 G>T | 5'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- ZNF764 | c.*1217T>C | 3'UTR (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
